Gene-level copy-number profile of tumor specimen TCGA-CN-6010-01A from TCGA case TCGA-CN-6010, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.3 years (19,475 days).
Specimen TCGA-CN-6010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cd742486-9322-4882-9285-d2d52c5f25c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6010-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e4e8565-d055-4f89-a7bc-67eeee21f141

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4; copy number 2: 12,892; copy number 3: 26,700; copy number 4: 16,131; copy number 5: 1,700; copy number 6: 688; copy number 7: 466; copy number 8: 193; copy number 10: 316; copy number 11: 712; copy number 12: 2; copy number 13: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6010-01A-11D-1682-01): tumor purity 0.41, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:76,880,175–76,958,638, 4 genes: KCTD12, AC000403.1, BTF3P11, ACOD1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,695 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,523,538–198,222,513, 933 genes, copy number 10–11 (broad region; genes not listed).
- chr4:51,843,000–75,814,286, 382 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr4:86,542,482–88,231,628, 38 genes, copy number 7 (within-gene range 2–7): MIR4452, PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7, IBSP, MEPE, HSP90AB3P, AC131944.1, SPP1, RNU1-36P, PKD2, ABCG2, AC097484.1.
- chr4:90,370,123–90,370,427, 1 gene, copy number 8: RN7SKP248.
- chr4:120,639,090–123,319,433, 39 genes, copy number 7–12: AC025741.1, PRDM5, RNU6-550P, SETP12, NDNF, RN7SKP137, AC105254.1, AC105254.2, TNIP3, RNU6-948P, QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5, AC026402.1.
- chr6:63,193,072–63,616,361, 15 genes, copy number 10: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr8:31,497,423–47,202,897, 265 genes, copy number 7–11 (broad region; genes not listed).
- chr9:133,250,401–133,575,519, 22 genes, copy number 8: ABO, Y_RNA, LCN1P2, SURF6, Y_RNA, MED22, AL772161.1, RPL7A, SNORD24, SNORD36B, SNORD36A, SNORD36C, SURF1, SURF2, SURF4, STKLD1, REXO4, ADAMTS13, CACFD1, SLC2A6, MYMK, ADAMTSL2.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
